Somatic mutation profile of tumor specimen TCGA-S9-A6WL-01A (aliquot TCGA-S9-A6WL-01A-21D-A33T-08) from TCGA case TCGA-S9-A6WL, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.7 years (19,234 days).
Specimen TCGA-S9-A6WL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cac03d0-af63-45b8-88a7-152a66078860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WL-10A (Blood Derived Normal), aliquot TCGA-S9-A6WL-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a77ec58-5294-4c36-9d87-683bca7a1528

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 8, In Frame Del 5, Nonsense Mutation 3, Splice Site 2, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 77/196 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALPI | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151137290; called by muse, mutect2, varscan2
- ANAPC5 | c.736T>A p.F246I | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.715); catalogued as COSV99946506; called by muse, mutect2, varscan2
- DDX60L | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757851536, COSV99488511; called by muse, mutect2, varscan2
- DNAJA4 | c.620_622del p.K207del (on ENST00000343789; = p.K236del on NM_018602.3) | In Frame Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs1279146209; called by pindel, varscan2
- ERBB4 | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99633680; called by muse, mutect2, varscan2
- GIMAP4 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs200017717, COSV55434308; called by muse, mutect2
- GRM5 | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100554643; called by muse, mutect2, varscan2
- H1-3 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV55097348, COSV99768902; called by muse, mutect2, varscan2
- HMCN1 | c.4111T>C p.S1371P | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99636172; called by muse, mutect2, varscan2
- INSIG2 | c.647_648del p.K216Sfs*30 | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | catalogued as rs974034957; called by mutect2, pindel, varscan2
- KRT71 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs781552402, COSV99922409; called by muse, mutect2, varscan2
- MAP2 | c.4766G>A p.G1589D | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561820; called by muse, mutect2, varscan2
- MMP15 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as COSV99539752; called by muse, mutect2, varscan2
- MRC1 | c.3959G>A p.W1320* | Nonsense Mutation (SNP) | VAF 152/446 reads (34%) | catalogued as rs782706044, COSV99519527; called by muse, mutect2, varscan2
- MSC | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100335937; called by muse, mutect2, varscan2
- MUC17 | c.5402C>T p.S1801L | Missense Mutation (SNP) | VAF 76/798 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs147751797; called by muse, mutect2
- MUC7 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs772332674, COSV59218518; called by muse, mutect2, varscan2
- MX2 | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58095214; called by muse, mutect2
- NCCRP1 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV100355897; called by muse, mutect2, varscan2
- NPAP1 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.35); catalogued as COSV61504768, COSV61506638; called by muse, mutect2
- OPRK1 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99654403; called by muse, mutect2, varscan2
- OR2A12 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs749631010, COSV68821215; called by muse, mutect2, varscan2
- RAPGEF6 | c.4157A>T p.D1386V | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV99728019; called by muse, mutect2
- RSF1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100408017; called by muse, mutect2, varscan2
- TMEM168 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 150/475 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201768776, COSV57182705; called by muse, mutect2, varscan2
- TMEM183A | c.1088_1089del p.F363* | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs1307158457; called by mutect2, varscan2
- TPX2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs781554900, COSV100302110; called by muse, mutect2
- ZBTB33 | c.1217C>A p.S406* | Nonsense Mutation (SNP) | VAF 6/125 reads (5%) | catalogued as COSV100434337; called by muse, mutect2
- ZNF106 | c.5275G>T p.D1759Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99783213; called by muse, mutect2
- ZNF142 | c.4273A>G p.I1425V (on ENST00000411696 / NM_001379660.1; = p.I1225V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101377006; called by muse, mutect2, varscan2
- ARID4B | c.2915_2916del p.V972Gfs*2 | Frame Shift Del (DEL) | VAF 81/333 reads (24%) | called by pindel, varscan2
- BCOR | c.2325dup p.H776Tfs*41 | Frame Shift Ins (INS) | VAF 47/268 reads (18%) | called by mutect2, pindel, varscan2
- C5orf24 | c.246_248del p.K82del | In Frame Del (DEL) | VAF 50/152 reads (33%) | called by pindel, varscan2
- CNTNAP4 | c.538+3_538+6del p.X180_splice | Splice Site (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- DHX29 | c.919_920del p.L307Rfs*7 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.1279_1281del p.K427del | In Frame Del (DEL) | VAF 16/148 reads (11%) | called by pindel, varscan2
- HEATR5B | c.4235_4238del p.E1412Vfs*22 | Frame Shift Del (DEL) | VAF 66/233 reads (28%) | called by mutect2, pindel, varscan2
- HECTD4 | c.12210_12213del p.F4071Afs*36 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.13529_13530+1del p.X4510_splice | Splice Site (DEL) | VAF 18/153 reads (12%) | called by pindel, varscan2
- LCE5A | c.195_215delinsGTGGCT p.G66_H72delinsWL | In Frame Del (DEL) | VAF 26/132 reads (20%) | called by pindel, varscan2*
- POTEE | c.2342A>G p.D781G | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- SEMA6D | c.533_534del p.F178Cfs*2 | Frame Shift Del (DEL) | VAF 16/183 reads (9%) | called by mutect2, pindel
- ZBTB20 | c.1848_1850del p.L617del (on ENST00000474710 / NM_001164342.2; = p.L544del on NM_015642.6 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 51/144 reads (35%) | called by mutect2, pindel, varscan2
- ZKSCAN2 | c.374_377del p.K125Rfs*5 | Frame Shift Del (DEL) | VAF 69/181 reads (38%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2274C>T p.S758= | Silent (SNP) | VAF 42/227 reads (19%) | catalogued as rs759343097, COSV99531028; called by muse, mutect2, varscan2
- CFAP61 | c.456T>C p.T152= | Silent (SNP) | VAF 71/285 reads (25%) | catalogued as COSV99846718; called by muse, mutect2, varscan2
- INPP5A | c.633C>T p.G211= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100704565; called by muse, varscan2
- KBTBD13 | c.153C>T p.G51= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs754453893, COSV71351761; called by muse, mutect2
- OR1A2 | c.609C>T p.V203= | Silent (SNP) | VAF 144/413 reads (35%) | catalogued as rs150553361; called by muse, mutect2, varscan2
- PLXND1 | c.3069G>A p.T1023= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs561945149, COSV60711580, COSV60720903; called by muse, mutect2
- PNPLA6 | c.4047C>T p.S1349= (on ENST00000414982 / NM_001166111.2; = p.S1301= on NM_006702.5) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs140501151; called by muse, varscan2
- PNPLA7 | c.3576G>A p.V1192= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs780478013, COSV99481461; called by muse, varscan2
- U2SURP | c.894A>C p.G298= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV101204594; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701058 G>A | 3'Flank (SNP) | VAF 32/137 reads (23%) | catalogued as rs376979668; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777722 C>T | 5'Flank (SNP) | VAF 10/45 reads (22%) | catalogued as rs566175911, COSV50487102; called by muse, mutect2, varscan2
